Gene-level copy-number profile of tumor specimen TCGA-IN-7806-01A from TCGA case TCGA-IN-7806, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 50.4 years (18,404 days).
Specimen TCGA-IN-7806-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.6b05921a-7242-4ac8-a683-fad1a82201ee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-7806-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1af11f55-7b6d-4c40-8bf0-bc1521f3efec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 16,916; copy number 2: 39,855; copy number 3: 2,936; copy number 4: 103.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-7806-01A-11D-2052-01): tumor purity 0.65, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr5:60,021,249–60,033,020, 1 gene: AC034234.1.
- chr16:6,573,767–6,577,359, 1 gene: AC007223.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 14,497. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
